TARGET case TARGET-20-PAVXNZ — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/85a15d56-9eaf-4642-bcec-d198d7736285

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.2 years (821 days); Year of diagnosis: 2013; Days to last follow up: 122 days; Sites of involvement: Central nervous system.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 122 days; Event-free: no event (relapse, second malignancy or death) recorded through day 122; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 26 ×10³/µL; Blast Count 39%; Bone Marrow blast count 39%.
- Minimal Residual Disease (Flow Cytometry): Positive.
- Minimal Residual Disease (Flow Cytometry): Negative.

Biospecimens (1 sample)
- Sample TARGET-20-PAVXNZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AML1031_20230720.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 122
- WBC at Diagnosis: 26
- Bone marrow leukemic blast percentage (%): 39
- Peripheral blasts (%): 39
- CNS disease: Yes
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: No
- Minus Y: No
- Minus X: No
- Cytogenetic Code Other: der(1)t(1;1)(p13;q25)t(1;13)(q23;q14),inv(1)(p13p31),t(7;13)(q31;q21),der(10)(10pter->10q26::1p11->1q23::13q13->13qter), der(13)t(1;13)(p12;q12),del(13)(q12.3q14.3),
- Cytogenetic Complexity: 6
- Primary Cytogenetic Code: Other
- ISCN: 46,XY,der(1)t(1;1)(p13;q25)t(1;13)(q23;q14),inv(1)(p13p31),t(7;13)(q31;q21),der(10)(10pter->10q26::1p11->1q23::13q13->13qter),der(13)t(1;13)(p12;q12),del(13)(q12.3q14.3),del(17)(p11.2p13)[9]
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- MRD at end of course 1: Yes
- MRD % at end of course 1: 1.2
- MRD at end of course 2: No
- MRD % at end of course 2: 0
- CR status at end of course 1: CR
- CR status at end of course 2: CR
- Risk group: Standard Risk
- SCT in 1st CR: No
